Gene-level copy-number profile of tumor specimen HCM-CSHL-0460-C50-01B from HCMI case HCM-CSHL-0460-C50, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 57.1 years (20,838 days).
Specimen HCM-CSHL-0460-C50-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f067bfd8-64bf-45bf-a277-65f321da07b3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0460-C50-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,237 have no estimate.
https://portal.gdc.cancer.gov/files/4b149caa-3926-44f1-b3d2-934c7b9ac33b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 64; copy number 1: 4,271; copy number 2: 49,846; copy number 3: 2,568; copy number 4: 1,622; copy number 5: 9; copy number 6: 1; copy number 7: 1; copy number 10: 3; copy number 17: 1.

Homozygous deletions (total copy number 0; autosomes only): 64 genes in 35 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,167,104–1,197,936, 6 genes: MIR200B, MIR200A, MIR429, AL390719.2, TTLL10-AS1, TTLL10.
- chr1:1,275,223–1,280,420, 1 gene: LINC01786.
- chr1:184,999,710–185,008,789, 1 gene: LINC01633.
- chr2:131,279,290–131,309,068, 2 genes (within-gene range 0–2): FAR2P4, KLF2P4.
- chr2:131,328,176–131,330,857, 1 gene (within-gene range 0–2): ARHGAP42P1.
- chr2:131,352,214–131,353,239, 1 gene (within-gene range 0–2): SSBP3P2.
- chr2:241,010,045–241,010,744, 1 gene (within-gene range 0–2): AC093585.1.
- chr3:126,973,065–127,037,392, 2 genes: AC011199.1, PLXNA1.
- chr4:1,167,778–1,168,174, 1 gene (within-gene range 0–1): AC092535.5.
- chr4:1,550,284–1,550,572, 1 gene: AC147067.2.
- chr4:13,540,830–13,547,801, 2 genes: NKX3-2, LINC01096.
- chr7:98,214,624–98,252,232, 1 gene: TECPR1.
- chr7:130,380,339–130,388,114, 1 gene: CPA1.
- chr8:140,511,311–140,517,154, 1 gene: CHRAC1.
- chr9:136,670,602–136,687,457, 2 genes (within-gene range 0–2): MIR126, AGPAT2.
- chr10:133,237,855–133,276,868, 5 genes: VENTX, MIR202HG, MIR202, AL592071.1, ADAM8.
- chr11:392,614–404,908, 1 gene: PKP3.
- chr14:102,501,676–102,509,799, 2 genes (within-gene range 0–2): RNU6-244P, ANKRD9.
- chr16:1,431,078–1,444,556, 3 genes: PERCC1, CCDC154, AL032819.2.
- chr16:1,445,343–1,452,653, 2 genes (within-gene range 0–3): AL031600.3, AL031600.1.
- chr16:89,113,175–89,115,279, 1 gene (within-gene range 0–1): AC135782.3.
- chr17:439,978–445,939, 1 gene: RFLNB.
- chr17:7,839,904–7,856,099, 2 genes: KDM6B, TMEM88.
- chr17:81,939,645–81,947,601, 2 genes (within-gene range 0–1): MYADML2, AC145207.1.
- chr17:82,018,702–82,031,151, 2 genes: CENPX, LRRC45.
- chr20:17,613,678–17,682,295, 1 gene: RRBP1.
- chr20:63,540,810–63,556,695, 3 genes: SRMS, AL121829.2, FNDC11.
- chr21:8,701,461–8,761,335, 2 genes: CR381572.1, LINC01666.
- chr22:18,855,621–18,858,640, 1 gene (within-gene range 0–1): BCRP7.
- chr22:18,906,238–18,947,741, 3 genes (within-gene range 0–2): AC007326.4, PRODH, AC007326.5.
- chr22:20,198,729–20,208,524, 2 genes: AC007663.2, LINC00896.
- chr22:22,283,928–22,294,794, 2 genes: AC245060.5, AC245060.2.
- chr22:29,720,003–29,731,833, 1 gene (within-gene range 0–1): CABP7.
- chr22:47,115,838–47,117,217, 1 gene (within-gene range 0–1): FP325331.1.
- chr22:48,489,553–48,850,912, 3 genes (within-gene range 0–1): TAFA5, Z84468.1, MIR4535.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 15 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:241,957,767–241,999,098, 3 genes, copy number 5: BECN2, CFL1P4, MAP1LC3C.
- chr8:7,170,550–7,191,563, 2 genes, copy number 5–10: SNRPCP15, RPS3AP33.
- chr11:369,499–382,117, 1 gene, copy number 5: B4GALNT4.
- chr11:118,606,440–118,658,031, 3 genes, copy number 5 (within-gene range 2–5): PHLDB1, AP000941.1, MIR6716.
- chr17:81,952,507–81,961,840, 1 gene, copy number 5: NOTUM.
- chr21:44,107,373–44,210,114, 2 genes, copy number 6–17 (within-gene range 4–17): PWP2, GATD3A.
- chr21:44,172,169–44,194,338, 2 genes, copy number 10: AP001056.2, AP001056.1.
- chr22:21,473,000–21,517,533, 1 gene, copy number 7: PI4KAP2.

Autosomal genes at a single copy (total copy number 1): 4,271. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
